Gene-level copy-number profile of tumor specimen TCGA-VD-AA8Q-01A from TCGA case TCGA-VD-AA8Q, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell melanoma, type B; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.0 years (26,285 days).
Specimen TCGA-VD-AA8Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UVM.1babcd58-08ae-43d0-b4b6-f5bc000b5ba6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VD-AA8Q-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-VD-AA8Q-01A|TCGA-VD-AA8Q-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fb1a4757-2790-4351-b107-47ec5c1d4b77

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,359; copy number 2: 53,900; copy number 3: 82; copy number 4: 1,465.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VD-AA8Q-01A-11D-A39V-01): tumor purity 0.93, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,938. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
